Somatic mutation profile of tumor specimen TCGA-ZF-AA53-01A (aliquot TCGA-ZF-AA53-01A-11D-A391-08) from TCGA case TCGA-ZF-AA53, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 60.3 years (22,035 days).
Specimen TCGA-ZF-AA53-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e2be62b-e217-4a4c-b67c-d31dcf0530eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA53-10A (Blood Derived Normal), aliquot TCGA-ZF-AA53-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5aac7195-f3e8-4597-97f3-edf16d36e14b

The open-access MAF lists 185 somatic variants for this specimen: 136 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 47, Nonsense Mutation 13, Frame Shift Del 3, Intron 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs968174625, COSV50306845; called by muse, mutect2, varscan2
- AC090517.4 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV50996315, COSV51001924; called by muse, mutect2
- AC098582.1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV52026060; called by muse, mutect2
- AC139530.2 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as COSV100230276, COSV61270728; called by muse, mutect2, varscan2
- ADCK2 | c.1567G>C p.V523L | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50783062, COSV50784008; called by muse, mutect2
- AKAP9 | c.11465G>A p.R3822K (on ENST00000359028; = p.R3798K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.273); catalogued as COSV62359650; called by muse, mutect2, varscan2
- AMTN | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.23); catalogued as rs185210496, COSV59490730; called by muse, mutect2, varscan2
- ANKRD24 | c.592C>G p.R198G | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV53671113, COSV53676450; called by muse, mutect2, varscan2
- ANKS4B | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as rs1455093839, COSV100289813; called by muse, mutect2
- ATP2A2 | c.2702C>G p.S901C | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57876542; called by muse, mutect2, varscan2
- ATP8A1 | c.3373G>C p.E1125Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0.048); catalogued as COSV52550638; called by muse, mutect2, varscan2
- ATXN2L | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57365598, COSV57374716; called by muse, mutect2
- BRSK1 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100510514; called by muse, mutect2, varscan2
- BUB1 | c.2296G>C p.E766Q | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV100241534, COSV57067869; called by muse, mutect2
- C12orf40 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100210040; called by muse, mutect2, varscan2
- CACNA2D1 | c.2557C>G p.L853V (on ENST00000356253 / NM_001366867.1; = p.L841V on NM_000722.4) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV100666393, COSV62395702; called by muse, mutect2, varscan2
- CCDC18 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.961); catalogued as COSV100159527; called by muse, mutect2
- CDC14A | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.141); catalogued as COSV60564621; called by muse, mutect2, varscan2
- CDK12 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV101420303, COSV70999322; called by muse, mutect2, varscan2
- CIT | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as COSV99949464; called by muse, mutect2
- CPNE5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55200845; called by muse, mutect2
- CPSF2 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54101297; called by muse, mutect2, varscan2
- CPSF6 | c.1499G>C p.S500T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV57015575, COSV57016134, COSV57018951; called by muse, mutect2, varscan2
- CSF2RB | c.2168C>G p.S723* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV99453798; called by muse, mutect2, varscan2
- CSNK1A1 | c.159del p.R53Sfs*36 | Frame Shift Del (DEL) | VAF 11/74 reads (15%) | catalogued as COSV99939508; called by mutect2, pindel, varscan2
- DCAF15 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.215); catalogued as COSV54334228; called by muse, mutect2, varscan2
- DCT | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100986192; called by muse, mutect2
- DHX16 | c.1306C>A p.L436I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV100905190; called by muse, mutect2
- DNAH17 | c.10226C>T p.A3409V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs199512383; called by muse, mutect2, varscan2
- DNTT | c.328T>C p.C110R | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV64522662; called by muse, mutect2
- DOCK7 | c.4484C>G p.S1495C (on ENST00000635253 / NM_001367561.1; = p.S1464C on NM_033407.3) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.593); catalogued as COSV99224246; called by muse, mutect2
- DSP | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1057522287, COSV65796826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELN | c.1486G>C p.G496R | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV52716771; called by muse, mutect2, varscan2
- EME2 | c.1069G>C p.D357H | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51603302; called by muse, mutect2, varscan2
- ERBB3 | c.3701C>G p.S1234C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57247135, COSV57248025, COSV57256413; called by muse, mutect2
- F2 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as CM000011, COSV61314756, COSV61318092; called by muse, mutect2, varscan2
- FAM13B | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50371846, COSV50376844; called by muse, mutect2, varscan2
- FAM184A | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 4/59 reads (7%) | catalogued as COSV100137737; called by muse, mutect2
- FAT1 | c.8138C>T p.S2713L | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.289); catalogued as COSV71675818, COSV71676303; called by muse, mutect2, varscan2
- FCF1 | c.589C>G p.R197G | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as COSV62043917, COSV62044610; called by muse, mutect2, varscan2
- FDPS | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV63115635; called by muse, mutect2, varscan2
- FDXR | c.1295C>G p.S432C (on ENST00000293195 / NM_024417.5; = p.S438C on NM_004110.6) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV99500931; called by muse, mutect2
- FLACC1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs377145516, COSV53784585; called by muse, mutect2
- FREM2 | c.7937C>T p.S2646L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV54855602; called by muse, mutect2
- GALNT1 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV52455334; called by mutect2, varscan2
- GATB | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.067); catalogued as COSV56134162; called by muse, mutect2, varscan2
- GNAT1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV50029225; called by muse, mutect2, varscan2
- GOLGA1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.137); catalogued as rs761134317, COSV52347586; called by muse, mutect2, varscan2
- GOLGB1 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as rs770087482, COSV61470800, COSV61472315; called by muse, mutect2, varscan2
- GOLGB1 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV61472322; called by muse, mutect2, varscan2
- GPR142 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as COSV59520361, COSV59520705; called by muse, mutect2, varscan2
- HAUS5 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV52547307; called by muse, mutect2, varscan2
- HEATR5B | c.4048C>G p.L1350V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV51860360; called by muse, mutect2, varscan2
- HIRIP3 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 17/191 reads (9%) | catalogued as COSV99663017; called by muse, mutect2
- HPS1 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV100282580; called by muse, mutect2
- HSPBAP1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.005); catalogued as COSV53750029; called by muse, mutect2
- HTR3A | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV55472041; called by muse, mutect2, varscan2
- IL6ST | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV61139748, COSV61143270; called by muse, mutect2, varscan2
- IRF5 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV50863022; called by muse, mutect2
- KDM6A | c.3549-1G>A p.X1183_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as rs796568156, CS1412301, COSV65036810, COSV65040147; called by muse, mutect2
- KIF15 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV58165349; called by muse, mutect2
- KLHL41 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs766932607, COSV52929326; called by muse, mutect2, varscan2
- KLK13 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs142773664; called by muse, mutect2, varscan2
- KRT84 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs878860575, COSV57771715; called by muse, mutect2, varscan2
- LBR | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as COSV55292332; called by muse, mutect2, varscan2
- LPP | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.917); catalogued as COSV57083459, COSV57118966; called by muse, varscan2
- LRP2 | c.12478G>C p.D4160H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55578951; called by muse, mutect2, varscan2
- MAPK4 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.099); catalogued as COSV68544196; called by muse, mutect2, varscan2
- MAVS | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV63927772; called by muse, mutect2
- MEGF8 | c.6847G>A p.E2283K (on ENST00000251268 / NM_001271938.2; = p.E2216K on NM_001410.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV52104530; called by muse, mutect2, varscan2
- MIA2 | c.1783C>G p.L595V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV54502862; called by muse, mutect2, varscan2
- MINPP1 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV64355769; called by muse, mutect2, varscan2
- NAP1L3 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV59078085; called by muse, mutect2, varscan2
- NCK2 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1402102793, COSV51897253; called by muse, mutect2, varscan2
- NDC80 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV55250149; called by muse, mutect2, varscan2
- NEK3 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99317570; called by muse, mutect2, varscan2
- NUP85 | c.1425G>A p.M475I | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV55459513; called by muse, mutect2, varscan2
- OPA1 | c.287G>C p.R96T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV62484030; called by muse, varscan2
- OR2L3 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 16/202 reads (8%) | catalogued as COSV100741960, COSV63455889; called by muse, mutect2
- OR5A1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57378810; called by muse, mutect2, varscan2
- OSBP2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs959966548, COSV100213057; called by muse, mutect2
- P3H2 | c.1822C>G p.L608V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV60029200; called by muse, mutect2, varscan2
- PARVG | c.249G>A p.Q83= | Splice Region (SNP) | VAF 12/56 reads (21%) | catalogued as rs967129078, COSV63563254; called by muse, varscan2
- PCDHGA2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV53956025; called by muse, mutect2
- PCYT1B | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV63266906; called by muse, mutect2, varscan2
- PDCD6IP | c.223A>T p.I75F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs745493460, COSV56246391; called by muse, mutect2, varscan2
- PDGFRB | c.2905-1G>C p.X969_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99641756; called by muse, mutect2, varscan2
- PHYH | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs769348267, COSV53815879; called by mutect2, varscan2
- PLEKHN1 | c.1619G>A p.G540E (on ENST00000379409; = p.G488E on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58024159; called by muse, mutect2, varscan2
- PON3 | c.683C>A p.S228* | Nonsense Mutation (SNP) | VAF 23/120 reads (19%) | catalogued as COSV55702267, COSV99672435; called by muse, mutect2, varscan2
- POU3F4 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100937233; called by muse, mutect2, varscan2
- PPFIBP2 | c.1079G>C p.R360T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV100206482; called by muse, mutect2
- PPP3CA | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59922825, COSV59932721; called by muse, mutect2, varscan2
- PREP | c.376C>T p.Q126* (on ENST00000369110; = p.Q192* on NM_002726.5) | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100963906; called by muse, mutect2, varscan2
- PRKCI | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55516485, COSV99855837; called by muse, mutect2, varscan2
- PSD2 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV51215331; called by muse, mutect2, varscan2
- PSMD2 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59531743; called by muse, mutect2, varscan2
- RBM5 | c.1896G>C p.E632D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV61739344; called by muse, mutect2
- RBMX | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV57811845; called by muse, mutect2, varscan2
- REPS2 | c.325T>C p.F109L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58178650, COSV58179410; called by muse, mutect2, varscan2
- RICTOR | c.709C>T p.H237Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV57132207; called by muse, varscan2
- RNF168 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs750787709, COSV58839846; called by muse, mutect2, varscan2
- ROPN1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV51741304; called by muse, mutect2, varscan2
- RSF1 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.143); catalogued as COSV57847045; called by muse, mutect2, varscan2
- RSRC2 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV59207417; called by muse, mutect2, varscan2
- SASH1 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV66566901; called by muse, mutect2, varscan2
- SERPINF1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756397389, COSV54618262; called by muse, mutect2, varscan2
- SLBP | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV59184567; called by muse, mutect2, varscan2
- SLC29A2 | c.993C>G p.I331M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV100237088; called by muse, mutect2
- SLC45A1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1453282886, COSV57101555; called by muse, mutect2, varscan2
- SLC7A5 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747364085, COSV55364181; called by muse, mutect2, varscan2
- SLCO1B3 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV53948176; called by muse, mutect2, varscan2
- SPATA7 | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50421145; called by muse, mutect2, varscan2
- SPSB3 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV99456954; called by muse, mutect2
- SRRM2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57081664; called by muse, mutect2, varscan2
- SULT1C3 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as rs1170744815, COSV61254836; called by muse, mutect2
- TBC1D19 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs1340558698, COSV53518837, COSV53522712; called by muse, mutect2, varscan2
- TCHH | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs746306176, COSV64278257; called by muse, mutect2, varscan2
- TMEM150C | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV71389679; called by muse, mutect2, varscan2
- TMEM94 | c.3631C>G p.L1211V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV58600929; called by muse, mutect2, varscan2
- TNFRSF10B | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99375369; called by muse, mutect2, varscan2
- TP53 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV52677652, COSV52734727, COSV52787469, COSV53371041; called by muse, mutect2, varscan2
- TP53 | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV53226525, COSV99400183; called by muse, mutect2
- TSC1 | c.569del p.R190Pfs*20 | Frame Shift Del (DEL) | VAF 26/89 reads (29%) | catalogued as rs118203401, CM090914, COSV100052877, COSV53764234, COSV53764966, COSV53768233; ClinVar: not provided; called by mutect2, pindel, varscan2
- TSNAX | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64147443; called by muse, mutect2
- VIRMA | c.5188C>T p.Q1730* | Nonsense Mutation (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99888279; called by muse, mutect2, varscan2
- WDR17 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); catalogued as COSV54575293, COSV54583940, COSV54586090; called by muse, mutect2, varscan2
- WHAMM | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.085); catalogued as rs1475673420, COSV54500230; called by muse, mutect2
- ZBTB40 | c.678G>C p.K226N | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs987767626, COSV100988937; called by muse, mutect2
- ZNF451 | c.2836C>T p.R946C (on ENST00000370706 / NM_001031623.3; = p.R898C on NM_015555.2) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs376330274; called by muse, mutect2, varscan2
- ZNF597 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs773056591, COSV57085991; called by muse, mutect2, varscan2
- MYO19 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- RBM10 | c.641dup p.N214Kfs*2 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- STAG2 | c.3403_3424del p.E1135Ifs*21 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- AIP | c.705C>T p.L235= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99069130, COSV99653659; called by muse, mutect2
- ANO1 | c.2505C>G p.L835= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV62448947; called by muse, mutect2
- ARHGAP19 | c.303C>T p.L101= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1241793564, COSV57396682; called by muse, varscan2
- ATP6V0A2 | c.2361C>T p.V787= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as COSV57752137; called by muse, mutect2, varscan2
- CDHR2 | c.2280G>T p.L760= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV56146467; called by muse, mutect2, varscan2
- CEP104 | c.1275G>A p.L425= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV65517979, COSV65520184; called by muse, mutect2, varscan2
- CEP162 | c.3666C>G p.L1222= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV57625841; called by muse, mutect2, varscan2
- CEP170 | c.1239C>G p.V413= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as COSV60513838, COSV60514592; called by muse, mutect2
- DISC1 | c.2214C>T p.S738= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs565912178, COSV64107243; called by muse, mutect2, varscan2
- ERBB3 | c.3415C>T p.L1139= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV57265103; called by muse, mutect2, varscan2
- FCGR1A | c.1053G>A p.L351= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100977285; called by mutect2, varscan2
- G6PC | c.1044C>T p.V348= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs975072899, COSV53833280; called by muse, mutect2, varscan2
- GABBR1 | c.2556C>G p.L852= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV63544964; called by muse, mutect2, varscan2
- GTPBP2 | c.858C>T p.L286= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs139289282; called by muse, mutect2
- HIRIP3 | c.660G>T p.L220= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV54229932, COSV54231997; called by muse, mutect2
- KDM3B | c.3804G>A p.P1268= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs751194137, COSV58696432; called by muse, mutect2, varscan2
- KIF9 | c.456C>A p.L152= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV55524132; called by muse, mutect2
- L3MBTL3 | c.2322G>A p.K774= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV62390175; called by muse, mutect2, varscan2
- LARP4B | c.1857C>T p.H619= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100295396, COSV60219977; called by muse, mutect2
- LARP4B | c.1701C>T p.L567= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1375543476, COSV60224514; called by muse, mutect2, varscan2
- MAPK14 | c.474G>C p.V158= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV100004871, COSV57696008; called by muse, mutect2
- MEF2A | c.135C>T p.L45= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV57533647, COSV57538266; called by muse, mutect2, varscan2
- NCOA3 | c.3183C>T p.L1061= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV59074413; called by muse, mutect2, varscan2
- NEK1 | c.3480G>A p.L1160= | Silent (SNP) | VAF 15/190 reads (8%) | catalogued as COSV71458378; called by muse, mutect2
- NPLOC4 | c.192C>G p.L64= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV58620591; called by muse, mutect2
- OPA1 | c.219G>A p.L73= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1296272210, COSV62484025; called by muse, varscan2
- OXR1 | c.2085G>A p.V695= (on ENST00000442977 / NM_001198532.1; = p.V667= on NM_018002.3) | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52428165; called by muse, mutect2, varscan2
- PAQR9 | c.495C>G p.G165= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100503793, COSV61419232; called by muse, mutect2, varscan2
- PCNX3 | c.3087C>T p.A1029= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV63141401; called by muse, mutect2, varscan2
- PI15 | c.300G>A p.S100= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as rs1423685861, COSV52640862, COSV52644839; called by muse, mutect2
- PICK1 | c.705G>C p.L235= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV63662280; called by muse, mutect2
- PIKFYVE | c.2043C>G p.V681= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV52250447; called by muse, mutect2, varscan2
- PPP1R10 | c.729C>G p.L243= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs1204901689, COSV64740695; called by muse, mutect2, varscan2
- RBM12 | c.1053C>G p.L351= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs760417413, COSV58295807; called by muse, mutect2, varscan2
- RICTOR | c.648C>T p.I216= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as rs370461335; called by muse, varscan2
- RNF113B | c.516G>A p.A172= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1566701902, COSV57435699; called by muse, mutect2
- RYR2 | c.10257C>T p.F3419= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs748715725, COSV63681983; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEC61A1 | c.543C>G p.L181= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV54579441, COSV99684810; called by muse, mutect2, varscan2
- SLC15A1 | c.624C>G p.L208= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV64713178; called by muse, mutect2, varscan2
- SLC35F3 | c.990G>C p.L330= (on ENST00000366617 / NM_001300845.1; = p.L399= on NM_173508.4) | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV64022081; called by muse, mutect2, varscan2
- SMCR8 | c.597G>A p.L199= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs751560607, COSV58181613; called by muse, mutect2, varscan2
- SPDYA | c.102G>A p.L34= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV61857783; called by muse, mutect2
- TBC1D8 | c.3366C>T p.L1122= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV51823292; called by muse, mutect2
- TENM3 | c.6099G>C p.V2033= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV69310778; called by muse, mutect2, varscan2
- THADA | c.5688G>A p.V1896= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV56700495; called by muse, mutect2, varscan2
- UIMC1 | c.1839G>A p.K613= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV65895404; called by muse, mutect2
- ZNF3 | c.711C>T p.F237= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs751630994, COSV52796667; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2329G>A | Intron (SNP) | VAF 13/68 reads (19%) | catalogued as rs779926819, COSV56705494; called by muse, mutect2, varscan2
- DNMT3A | c.640-1431C>T | Intron (SNP) | VAF 13/74 reads (18%) | catalogued as rs151168784; called by muse, mutect2, varscan2
